Gene-level copy-number profile of tumor specimen TCGA-04-1514-01A from TCGA case TCGA-04-1514, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 45.8 years (16,725 days).
Specimen TCGA-04-1514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a059d969-2eb2-44d5-93cd-ed88f5b61719.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1514-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1db8cc8c-189d-4c1f-a3eb-29ff17ce79cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,400; copy number 2: 23,560; copy number 3: 19,776; copy number 4: 5,522; copy number 5: 6,526; copy number 6: 1,455; copy number 7: 36; copy number 8: 250; copy number 9: 179; copy number 10: 8; copy number 11: 43; copy number 15: 18; copy number 21: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1514-01): tumor purity 0.93, ploidy 2.88, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,560 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:9,498,361–10,708,007, 50 genes, copy number 6 (within-gene range 3–6): LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13, ATP2B2, MIR378B, MIR885, ATP2B2-IT1, ATP2B2-IT2.
- chr3:160,677,160–187,805,258, 434 genes, copy number 5–21 (broad region; genes not listed).
- chr5:58,198–20,937,800, 360 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:92,410,256–93,068,669, 8 genes, copy number 5 (within-gene range 3–5): AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1.
- chr6:69,672,757–70,957,060, 20 genes, copy number 5: LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2.
- chr6:104,831,129–109,094,819, 89 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr7:57,402,181–159,233,377, 1,965 genes, copy number 5 (broad region; genes not listed).
- chr11:31,509,755–32,104,665, 6 genes, copy number 8 (within-gene range 3–8): ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1.
- chr11:42,939,775–43,066,076, 3 genes, copy number 5: AC109810.1, AC009643.2, AC009643.1.
- chr11:68,870,664–79,441,030, 328 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:81,175,201–81,556,425, 3 genes, copy number 6 (within-gene range 3–6): AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,890,836, 2 genes, copy number 6: AP002802.2, MIR4300.
- chr11:85,336,075–91,015,299, 140 genes, copy number 6 (broad region; genes not listed).
- chr11:114,400,030–117,817,525, 68 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr13:18,467,172–20,773,961, 79 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–23,645,639, 403 genes, copy number 5 (broad region; genes not listed).
- chr14:24,809,656–39,432,500, 229 genes, copy number 5 (broad region; genes not listed).
- chr14:40,630,006–79,868,291, 769 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:80,476,983–88,881,078, 85 genes, copy number 5 (broad region; genes not listed).
- chr15:43,369,221–44,884,694, 52 genes, copy number 5 (within-gene range 2–5): TUBGCP4, RN7SL487P, TP53BP1, MAP1A, PPIP5K1, CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1, CKMT1A, STRCP1, RNU6-353P, CATSPER2P1, RNU6-354P, PDIA3, ELL3, AC018512.1, SERF2, MIR1282, SERINC4, HYPK, MFAP1, WDR76, Y_RNA, FRMD5, PIN4P1, ACTBP7, GAPDHP55, GOLM2, GAPDHP43, AC090519.1, AC025043.1, CTDSPL2, HNRNPMP1, AC025430.1, EIF3J-DT, EIF3J, AC009996.1, SPG11, PATL2, Y_RNA, B2M, TRIM69, AC122108.2, SORD2P, AC122108.1, Y_RNA.
- chr17:54,702,936–55,327,791, 11 genes, copy number 5: AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1.
- chr17:55,719,627–55,872,939, 3 genes, copy number 5: TMEM100, PCTP, AC090618.1.
- chr17:56,368,063–56,368,215, 1 gene, copy number 5: AC006600.1.
- chr17:56,791,913–58,219,605, 51 genes, copy number 5: C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P, RNU7-134P, CCDC182, AC015845.2, RN7SKP94, MRPS23, CUEDC1, AC015845.1, AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.8, AC015813.3, DYNLL2, AC015813.6, OR4D1, MSX2P1, OR4D2, EPX, AC005962.1, MKS1.
- chr17:77,014,880–82,648,553, 244 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr19:4,969,113–21,678,221, 889 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:27,638,483–39,644,612, 442 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).
- chr21:10,328,411–33,265,675, 368 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
